Gene-level copy-number profile of tumor specimen TCGA-22-5489-01A from TCGA case TCGA-22-5489, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.7 years (23,618 days).
Specimen TCGA-22-5489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.98a328df-20fc-440d-9e7d-00569c3a9809.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5489-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f92a0bcc-354b-409f-abfd-1a8553d42ede

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 152; copy number 1: 10,921; copy number 2: 35,077; copy number 3: 9,401; copy number 4: 2,534; copy number 5: 1,613; copy number 6: 118.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5489-01A-01D-1631-01): tumor purity 0.43, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:156,662,050–157,210,779, 7 genes (within-gene range 0–1): H3P28, AL355297.2, ARID1B, AL355297.3, MIR4466, AL355297.1, AL162578.1.
- chr9:21,239,002–30,935,977, 108 genes (broad region; genes not listed).
- chr16:50,548,396–50,649,249, 1 gene (within-gene range 0–1): NKD1.
- chr16:50,606,076–51,671,563, 28 genes: AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1, HNRNPA1P48, RN7SKP142.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,731 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:105,655,461–115,564,389, 162 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:147,844,123–161,326,219, 254 genes, copy number 5 (broad region; genes not listed).
- chr3:161,816,909–162,601,792, 3 genes, copy number 5: AC131211.1, TOMM22P6, AC128716.1.
- chr3:167,441,789–198,222,513, 611 genes, copy number 5 (broad region; genes not listed).
- chr9:11,618,496–15,465,953, 47 genes, copy number 5 (within-gene range 2–5): AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P.
- chr9:33,104,082–35,592,951, 118 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–16,037,381, 536 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,543. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
